Somatic mutation profile of tumor specimen TCGA-V1-A9ZR-01A (aliquot TCGA-V1-A9ZR-01A-11D-A41K-08) from TCGA case TCGA-V1-A9ZR, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland.
Specimen TCGA-V1-A9ZR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5e0cd69f-8ef8-4b60-b58e-1c26044e759f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-V1-A9ZR-10A (Blood Derived Normal), aliquot TCGA-V1-A9ZR-10A-01D-A41N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4f94c76d-8e30-4c22-822c-de1c03c795b3

The open-access MAF lists 37 somatic variants for this specimen: 27 protein-altering or splice-affecting, 7 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 7, RNA 2, Splice Site 2, Nonsense Mutation 1, 5'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AQP9 | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 42/172 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.498); catalogued as rs746791248, COSV99582955; called by muse, mutect2, varscan2
- ARFGAP3 | c.1320+2T>A p.X440_splice | Splice Site (SNP) | VAF 28/114 reads (25%) | catalogued as COSV99605314; called by muse, mutect2, varscan2
- ARHGAP39 | c.56C>T p.S19L | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); catalogued as rs1194445331, COSV99431435; called by muse, mutect2, varscan2
- ARMC9 | c.848C>T p.A283V | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.073); catalogued as rs781051576, COSV63023275; called by muse, mutect2, varscan2
- BPIFB2 | c.1006C>T p.R336W | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs144321606, COSV99401428; called by muse, mutect2, varscan2
- CAMK2A | c.1346C>T p.S449L (on ENST00000348628 / NM_171825.2; = p.S460L on NM_015981.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.878); catalogued as rs777247730, COSV100652043; called by muse, mutect2, varscan2
- CAMKMT | c.177T>A p.H59Q | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as COSV101034833; called by muse, mutect2, varscan2
- CARD14 | c.2507C>T p.A836V | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs368705564; called by muse, mutect2, varscan2
- CHSY3 | c.1297A>C p.K433Q | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.166); catalogued as rs890910139, COSV100519221; called by muse, mutect2, varscan2
- DAPP1 | c.217T>A p.S73T | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99596890; called by muse, mutect2
- DOP1A | c.2093C>T p.S698F | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.14); catalogued as COSV52716888, COSV99382033; called by muse, mutect2, varscan2
- DOP1A | c.5650C>T p.Q1884* | Nonsense Mutation (SNP) | VAF 9/42 reads (21%) | catalogued as rs1252582782, COSV99382035; called by muse, mutect2, varscan2
- FBN1 | c.2114-2A>T p.X705_splice | Splice Site (SNP) | VAF 23/113 reads (20%) | catalogued as CS077353, COSV100355268; called by muse, mutect2, varscan2
- GABBR2 | c.949G>A p.V317M | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52294276; called by muse, mutect2, varscan2
- GRIN1 | c.271C>A p.L91I | Missense Mutation (SNP) | VAF 32/146 reads (22%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.843); catalogued as COSV100160345, COSV59300920; called by muse, mutect2, varscan2
- GSN | c.541C>T p.P181S | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs761433282, COSV100376260; called by muse, mutect2, varscan2
- GUF1 | c.1148A>C p.D383A | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1439961015, COSV99877308; called by muse, mutect2, varscan2
- IGKV1D-16 | c.72C>G p.I24M | Missense Mutation (SNP) | VAF 35/214 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1269052069; called by muse, mutect2, varscan2
- OTOA | c.1928G>A p.R643H (on ENST00000286149; = p.R629H on NM_144672.4) | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as rs755933684, COSV53758132, COSV99624681; called by muse, mutect2, varscan2
- PUM1 | c.2737C>G p.Q913E | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99928136; called by muse, mutect2, varscan2
- SLCO3A1 | c.334G>A p.G112S | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59229961; called by muse, mutect2
- SYNE2 | c.9634A>G p.I3212V | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs377100573, COSV59977846; called by muse, mutect2, varscan2
- TANC2 | c.1466G>A p.R489Q | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.871); catalogued as COSV67343701; called by muse, mutect2, varscan2
- TIAM2 | c.1144C>T p.R382W | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772490486, COSV100019220; called by muse, mutect2, varscan2
- TROAP | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs138091021; called by muse, mutect2, varscan2
- UGT2A3 | c.904A>T p.I302F | Missense Mutation (SNP) | VAF 46/177 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV99279888; called by muse, mutect2, varscan2
- ERF | c.291del p.K98Rfs*173 | Frame Shift Del (DEL) | VAF 27/131 reads (21%) | called by mutect2, pindel, varscan2
- CPXM2 | c.1110C>T p.P370= | Silent (SNP) | VAF 17/72 reads (24%) | catalogued as rs745538812, COSV53872314; called by muse, mutect2, varscan2
- ETV3L | c.459G>A p.A153= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as rs550855165, COSV101485591; called by muse, mutect2, varscan2
- IKZF1 | c.342C>T p.N114= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as rs185632810; called by muse, mutect2, varscan2
- KATNAL2 | c.237T>C p.Y79= (on ENST00000356157 / NM_001353899.1; = p.Y7= on NM_031303.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 41/174 reads (24%) | catalogued as rs780068234, COSV99796784; called by muse, mutect2, varscan2
- LCE1E | c.261T>C p.R87= | Silent (SNP) | VAF 16/66 reads (24%) | catalogued as rs1463316278, COSV100908551; called by muse, mutect2, varscan2
- NUB1 | c.291A>T p.G97= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as COSV100879290; called by muse, mutect2, varscan2
- ZNF205 | c.1629G>A p.A543= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs758868755, COSV54619778; called by muse, varscan2
- AP000769.3 | chr11:65502720 A>C | 5'Flank (SNP) | VAF 4/20 reads (20%) | called by muse, mutect2, varscan2
- C1orf220 | n.433G>A | RNA (SNP) | VAF 3/12 reads (25%) | called by muse, mutect2
- HERC2P3 | n.1776C>A | RNA (SNP) | VAF 25/209 reads (12%) | called by muse, mutect2, varscan2
